Somatic mutation profile of tumor specimen MMRF_2532_1_BM_CD138pos (aliquot MMRF_2532_1_BM_CD138pos_T1_KHS5U_K15156) from MMRF case MMRF_2532, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.8 years (26,940 days).
Specimen MMRF_2532_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f018ab3-f0ec-438e-ac27-5faacbd3814a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2532_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2532_1_PB_Whole_C3_KHS5U_K15155; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97fdebfc-dd4d-453d-8cbc-eca71226edc4

The open-access MAF lists 131 somatic variants for this specimen: 59 protein-altering or splice-affecting, 10 silent, 62 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 34, Intron 17, Silent 10, 5'UTR 7, Nonsense Mutation 4, 3'Flank 3, Splice Site 3, Frame Shift Del 2, Frame Shift Ins 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS14 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs780210737, COSV64600981; called by muse, mutect2, varscan2
- ANKRD31 | c.4263dup p.Q1422Tfs*12 | Frame Shift Ins (INS) | VAF 86/160 reads (54%) | catalogued as rs530301594; called by mutect2, varscan2
- BRCA2 | c.9966G>A p.M3322I | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV66337174; called by muse, mutect2, varscan2
- DAO | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs775565169, COSV57321261; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 121/271 reads (45%) | catalogued as rs782442161; called by mutect2, pindel, varscan2
- DUSP2 | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV56619478; called by muse, mutect2, varscan2
- ELANE | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.578); catalogued as rs201788817, CM104207, COSV55048287; called by muse, mutect2, varscan2
- ERCC3 | c.119C>T p.S40L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as rs1251238422; called by muse, mutect2, varscan2
- FAM135B | c.2242A>G p.T748A | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs756675839; called by muse, mutect2, varscan2
- FLNB | c.6011G>A p.R2004Q | Missense Mutation (SNP) | VAF 82/282 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs556342744, COSV55878664; called by muse, mutect2, varscan2
- IGHV1-24 | c.284C>T p.T95I | Missense Mutation (SNP) | VAF 137/139 reads (99%) | SIFT tolerated (0.47); PolyPhen benign (0.097); catalogued as rs1555470045; called by muse, mutect2, varscan2
- IGHV2-70 | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs777686921; called by muse, varscan2
- IGHV2-70 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs530408879; called by muse, varscan2
- IGLL5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as rs538723125, COSV73251010, COSV73251135, COSV73251305; called by muse, mutect2, varscan2
- IGLV3-1 | c.104A>T p.Q35L | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs533329143; called by muse, varscan2
- KLC3 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 49/386 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1168809559; called by muse, mutect2, varscan2
- LIN37 | c.162-3C>T | Splice Region (SNP) | VAF 20/45 reads (44%) | catalogued as rs754202563; called by muse, mutect2, varscan2
- LRRK1 | c.2941G>T p.A981S | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV52601592, COSV52606441; called by muse, mutect2, varscan2
- NUP153 | c.3158T>C p.I1053T | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs146551209; called by muse, mutect2, varscan2
- OR6B1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs541875791, COSV68770325; called by muse, mutect2, varscan2
- PCDHGA6 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.233); catalogued as rs1327188211, COSV53942235; called by muse, mutect2
- RANBP3L | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as rs199694826; called by muse, mutect2, varscan2
- SGIP1 | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376861429; called by muse, varscan2
- SHBG | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs576578590; called by muse, mutect2, varscan2
- TBC1D8 | c.168T>A p.N56K | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs759810790; called by muse, mutect2, varscan2
- TMPRSS15 | c.496+2T>C p.X166_splice | Splice Site (SNP) | VAF 36/68 reads (53%) | catalogued as rs543669116; called by muse, varscan2
- ZFYVE16 | c.3544G>T p.E1182* | Nonsense Mutation (SNP) | VAF 49/143 reads (34%) | catalogued as COSV62015165, COSV62016224; called by muse, mutect2, varscan2
- ANP32D | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 19/133 reads (14%) | called by muse, mutect2, varscan2
- BSCL2 | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMYA5 | c.5098C>G p.L1700V | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIA2 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2
- HCN1 | c.1023G>A p.W341* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- HECTD1 | c.108G>C p.L36F | Missense Mutation (SNP) | VAF 74/288 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- IGHV2-70 | c.339_341delinsTT p.Y114Ffs*? | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by pindel, varscan2*
- KIF25 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LDLRAD3 | c.823C>G p.P275A | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRP1B | c.7229G>A p.S2410N | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MAGEC2 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MNT | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- N4BP2 | c.3471G>T p.L1157F | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- NFKB2 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | called by muse, varscan2
- NSD1 | c.4477A>G p.K1493E | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR51A7 | c.489A>C p.L163F | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLOD2 | c.1426_1427del p.M476Efs*2 | Frame Shift Del (DEL) | VAF 22/142 reads (15%) | called by mutect2, pindel, varscan2
- PRKACA | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, varscan2
- RIN3 | c.224G>C p.R75T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.107); called by muse, mutect2
- RNASEH1 | c.172T>A p.F58I | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SCRT1 | c.934A>C p.S312R | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- SETD5 | c.959+2T>A p.X320_splice | Splice Site (SNP) | VAF 30/192 reads (16%) | called by muse, mutect2, varscan2
- SPPL2B | c.553A>C p.T185P | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SPTBN5 | c.4274T>C p.L1425P | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TENT5C | c.129_140del p.E45_L48del | In Frame Del (DEL) | VAF 16/92 reads (17%) | called by pindel, varscan2*
- TET2 | c.3300_3301insA p.L1101Tfs*3 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- TMEM132C | c.3250T>A p.W1084R | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMEM145 | c.59T>G p.L20R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- TOMM70 | c.1634A>G p.D545G | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, varscan2
- UGGT1 | c.4664T>C p.L1555S | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- XIRP2 | c.4937T>G p.M1646R (on ENST00000628543; = p.M1821R on NM_152381.6) | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2
- ZC3H12A | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- BCL3 | c.15C>T p.P5= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- CSPG4 | c.4161C>T p.F1387= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- DST | c.10827T>C p.L3609= | Silent (SNP) | VAF 23/165 reads (14%) | catalogued as rs1290574331; called by muse, mutect2, varscan2
- FAT1 | c.7545A>G p.K2515= | Silent (SNP) | VAF 21/102 reads (21%) | called by muse, mutect2, varscan2
- GRIK5 | c.1182C>T p.N394= | Silent (SNP) | VAF 59/134 reads (44%) | catalogued as rs1436166731, COSV53480615; called by muse, mutect2, varscan2
- IGHV1-69D | c.288C>T p.S96= | Silent (SNP) | VAF 99/210 reads (47%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.315C>T p.Y105= | Silent (SNP) | VAF 86/212 reads (41%) | catalogued as rs373828762; called by muse, varscan2
- TFR2 | c.1512C>T p.Y504= | Silent (SNP) | VAF 33/222 reads (15%) | catalogued as rs761009757; called by muse, mutect2, varscan2
- TPTE | c.147A>G p.A49= | Silent (SNP) | VAF 50/215 reads (23%) | called by muse, mutect2, varscan2
- YY1AP1 | c.384T>C p.F128= (on ENST00000295566 / NM_139118.2; = p.F51= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/177 reads (50%) | called by muse, mutect2, varscan2
- ABCF2-H2BE1 | c.819-152G>A | Intron (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- ACTN4 | c.*904G>C | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- AKAP6 | c.3148-1232_3148-1231insT | Intron (INS) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- ANKRD28 | c.*2399C>A | 3'UTR (SNP) | VAF 41/121 reads (34%) | called by muse, mutect2, varscan2
- ARMC1 | c.*1277A>G | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- BTBD3 | c.-373T>G | 5'UTR (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- CACNA1C | c.3828+903C>T | Intron (SNP) | VAF 56/120 reads (47%) | catalogued as rs771576026; called by muse, mutect2, varscan2
- CACNA1E | c.*7853T>A | 3'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- CD93 | c.*2050A>T | 3'UTR (SNP) | VAF 16/84 reads (19%) | called by muse, mutect2, varscan2
- DBN1 | c.956-368C>T | Intron (SNP) | VAF 32/66 reads (48%) | called by muse, varscan2
- DCTN4 | c.*995G>A | 3'UTR (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.*2089C>T | 3'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- DEPDC5 | c.*515C>T | 3'UTR (SNP) | VAF 9/48 reads (19%) | catalogued as rs762073691; called by muse, mutect2, varscan2
- DNAH8 | c.-212C>T | 5'UTR (SNP) | VAF 71/158 reads (45%) | catalogued as rs1203659491; called by muse, mutect2, varscan2
- DPH6 | c.*1053T>C | 3'UTR (SNP) | VAF 22/160 reads (14%) | called by muse, mutect2, varscan2
- EHMT1 | c.1647+60_1647+66del | Intron (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- FICD | c.*843G>A | 3'UTR (SNP) | VAF 17/111 reads (15%) | catalogued as rs761419823; called by muse, mutect2, varscan2
- FRZB | c.*770A>G | 3'UTR (SNP) | VAF 14/67 reads (21%) | called by muse, mutect2, varscan2
- GLB1L2 | c.*116T>A | 3'UTR (SNP) | VAF 55/126 reads (44%) | called by muse, mutect2, varscan2
- GORAB | c.62-23T>G | Intron (SNP) | VAF 60/122 reads (49%) | called by muse, mutect2, varscan2
- GRIK2 | c.*139C>A | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- GRIK4 | chr11:120987563 C>T | 3'Flank (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- HOXA13 | c.*1733G>C | 3'UTR (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- IGF2BP1 | c.*3295A>T | 3'UTR (SNP) | VAF 57/143 reads (40%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.-49T>C | 5'UTR (SNP) | VAF 14/14 reads (100%) | catalogued as rs782579326; called by mutect2, varscan2
- KLLN | c.-756T>G | 5'UTR (SNP) | VAF 168/223 reads (75%) | catalogued as rs1554889807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA1 | c.8094+25A>G | Intron (SNP) | VAF 33/223 reads (15%) | called by muse, mutect2, varscan2
- LCN10 | c.258-263G>A | Intron (SNP) | VAF 104/306 reads (34%) | catalogued as rs199856415; called by muse, varscan2
- LCP2 | c.622-179G>T | Intron (SNP) | VAF 39/130 reads (30%) | called by muse, mutect2, varscan2
- LPP | c.*5421A>C | 3'UTR (SNP) | VAF 15/143 reads (10%) | called by muse, mutect2, varscan2
- LST1 | c.*35G>A | 3'UTR (SNP) | VAF 94/474 reads (20%) | called by muse, mutect2, varscan2
- MAF | c.*1357A>G | 3'UTR (SNP) | VAF 41/42 reads (98%) | called by muse, mutect2, varscan2
- MTMR10 | c.-58G>A | 5'UTR (SNP) | VAF 32/109 reads (29%) | catalogued as COSV101437434; called by muse, mutect2, varscan2
- NDC1 | c.*1572G>C | 3'UTR (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- NECTIN3 | c.*7T>A | 3'UTR (SNP) | VAF 34/223 reads (15%) | called by muse, mutect2, varscan2
- NOVA1 | c.519+2184del | Intron (DEL) | VAF 3/34 reads (9%) | called by muse*, pindel, varscan2*
- NPR3 | c.*3514T>G | 3'UTR (SNP) | VAF 38/251 reads (15%) | called by muse, mutect2, varscan2
- NRK | c.-43G>A | 5'UTR (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- PANK2 | chr20:3925770 del C | 3'Flank (DEL) | VAF 41/285 reads (14%) | called by mutect2, pindel, varscan2
- PCDHGA3 | c.2425-67950A>G | Intron (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- PDE4DIP | c.4704-41G>A | Intron (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- PGAP4 | c.*118G>T | 3'UTR (SNP) | VAF 16/123 reads (13%) | called by muse, mutect2, varscan2
- PITRM1 | c.2646-860T>G | Intron (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- PLEKHA1 | c.*2167C>G | 3'UTR (SNP) | VAF 20/116 reads (17%) | catalogued as COSV64569862; called by muse, varscan2
- PLEKHA1 | c.*2294_*2295del | 3'UTR (DEL) | VAF 12/105 reads (11%) | called by pindel, varscan2
- PLEKHG3 | c.*167C>T | 3'UTR (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- RABL3 | c.*1429G>A | 3'UTR (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- SEMA3C | c.*121A>G | 3'UTR (SNP) | VAF 20/37 reads (54%) | called by muse, mutect2, varscan2
- SGK1 | c.77-43A>C | Intron (SNP) | VAF 170/400 reads (43%) | called by muse, mutect2, varscan2
- SLIT3 | c.*3550C>T | 3'UTR (SNP) | VAF 22/96 reads (23%) | catalogued as rs564853834; called by muse, mutect2, varscan2
- SPRED1 | c.*895A>C | 3'UTR (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- ST8SIA1 | c.*377G>T | 3'UTR (SNP) | VAF 44/93 reads (47%) | called by muse, mutect2, varscan2
- STC2 | c.*2276C>T | 3'UTR (SNP) | VAF 13/128 reads (10%) | catalogued as rs139081944; called by muse, mutect2, varscan2
- STOML1 | c.134-383C>G | Intron (SNP) | VAF 22/171 reads (13%) | called by muse, mutect2, varscan2
- TACC2 | c.33+19C>T | Intron (SNP) | VAF 359/488 reads (74%) | called by muse, mutect2, varscan2
- THRB | c.*1741A>G | 3'UTR (SNP) | VAF 40/99 reads (40%) | catalogued as rs551911618, COSV54979284; called by muse, varscan2
- TMEM241 | c.383+705G>T | Intron (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- VASH2 | chr1:212989593 ins A | 3'Flank (INS) | VAF 22/83 reads (27%) | catalogued as rs1558156011; called by mutect2, pindel, varscan2
- ZFP36 | c.-6C>T | 5'UTR (SNP) | VAF 212/345 reads (61%) | catalogued as COSV50530599, COSV99953891; called by muse, mutect2, varscan2
- ZNF324B | chr19:58451621 T>C | 5'Flank (SNP) | VAF 61/186 reads (33%) | called by muse, mutect2, varscan2
- ZNF385D | c.*1838T>G | 3'UTR (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- ZNF880 | c.*83T>G | 3'UTR (SNP) | VAF 17/305 reads (6%) | called by muse, mutect2
